CCDI case PBCFRR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/129099e4-a629-49a0-8c16-e658d5bed510

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neuroepithelioma, NOS: ICD-O-3 morphology code: 9503/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,420 days).

Biospecimens (3 samples)
- Sample 0DRB5G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRB5R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRB5U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
